Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIB, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIB-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 4.0 cm; no angio-invasion; focal invasion of rete testis; no invasion of tunica albuginea and epididymis. The cord is not involved, including the resection margin.

Date of procurement (= date of orchidectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
9/3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 10af27d2-e6cf-4e97-9568-780144328ecd (TCGA-2G-AAIB-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).